Somatic mutation profile of tumor specimen TCGA-EE-A17X-06A (aliquot TCGA-EE-A17X-06A-11D-A197-08) from TCGA case TCGA-EE-A17X, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.3 years (20,576 days).
Specimen TCGA-EE-A17X-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cc70382-3d73-4e0d-bc93-c00ccc68528a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A17X-10A (Blood Derived Normal), aliquot TCGA-EE-A17X-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0bb8e5b0-ec72-48c2-8bc3-a4fa1830d7b2

The open-access MAF lists 968 somatic variants for this specimen: 641 protein-altering or splice-affecting, 304 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 577, Silent 304, Nonsense Mutation 47, Intron 10, 3'UTR 7, Splice Site 6, Splice Region 6, Frame Shift Del 4, RNA 4, Translation Start Site 1, 3'Flank 1, 5'UTR 1.

Variants (750 of 968; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3316G>T p.G1106* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as rs1554084921, COSV57344195, COSV57345889; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.1288C>T p.Q430* (on ENST00000361925 / NM_001375343.1; = p.Q390* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 41/51 reads (80%) | catalogued as rs121909674, CM020146, COSV62718182, COSV62723438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2198G>A p.G733E | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504241, CM031275, CM1411008, COSV100806141; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 154/175 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- OTOGL | c.574C>T p.R192* (on ENST00000547103; = p.R183* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as rs397514588, CM1210228, COSV72006650; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 46/98 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs797045942, CM159931, COSV51842015; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SOS1 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 30/54 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101216954; called by muse, mutect2, varscan2
- AAMDC | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59018190; called by muse, mutect2, varscan2
- ABCB1 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs199779996, COSV55951981; ClinVar: drug response; called by muse, mutect2, varscan2
- ABCG1 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.135); catalogued as COSV59204526; called by muse, mutect2, varscan2
- ABRA | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs868120866, COSV61732470; called by muse, varscan2
- AC004593.2 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); catalogued as COSV56092581; called by muse, mutect2, varscan2
- ACAD10 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.272); catalogued as COSV58157474; called by muse, mutect2, varscan2
- ACVR1B | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as COSV57777298; called by muse, mutect2, varscan2
- ADAM2 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs866239502, COSV55860219; called by muse, mutect2, varscan2
- ADAMTS18 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs868333047, COSV51411009, COSV99273813; called by muse, mutect2, varscan2
- ADCY10 | c.4151A>G p.D1384G | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV63240981; called by muse, mutect2, varscan2
- ADD2 | c.1742G>A p.G581E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52461370; called by muse, mutect2, varscan2
- ADD3 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53322471; called by muse, mutect2, varscan2
- ADGRB3 | c.4053G>A p.M1351I | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53240162, COSV53257873; called by muse, mutect2, varscan2
- ADGRG6 | c.2759G>A p.W920* | Nonsense Mutation (SNP) | VAF 40/115 reads (35%) | catalogued as COSV99747346; called by muse, mutect2, varscan2
- ADGRG6 | c.2760G>A p.W920* | Nonsense Mutation (SNP) | VAF 41/117 reads (35%) | catalogued as COSV51588296; called by muse, mutect2, varscan2
- ADGRL1 | c.2101G>A p.E701K (on ENST00000340736 / NM_001008701.3; = p.E696K on NM_014921.5) | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV100529543; called by muse, mutect2, varscan2
- ADGRV1 | c.1367T>C p.L456P | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774659694, COSV67985614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.4640C>T p.S1547F | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV67985618; called by muse, mutect2, varscan2
- ADH7 | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV52920909; called by muse, mutect2, varscan2
- AFM | c.486T>G p.F162L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV56920210; called by muse, mutect2, varscan2
- AHNAK | c.7225C>T p.P2409S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57214284; called by muse, mutect2, varscan2
- AHNAK | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as COSV57214301; called by muse, mutect2, varscan2
- AHNAK2 | c.15163G>T p.G5055W | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60907193, COSV60909810, COSV60915841; called by muse, mutect2, varscan2
- AHNAK2 | c.5582C>T p.S1861F | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as rs779504897, COSV100317593; called by muse, mutect2, varscan2
- ALB | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55738311; called by muse, mutect2, varscan2
- ALKAL1 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.555); catalogued as COSV62130396; called by muse, mutect2, varscan2
- ALPI | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs200399293, COSV55015166; called by muse, mutect2, varscan2
- ALPK1 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51585255; called by muse, mutect2, varscan2
- ALPK3 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV51933556; called by muse, mutect2, varscan2
- AMER3 | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV58466884; called by muse, mutect2, varscan2
- AMPH | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57742560, COSV57752055; called by muse, mutect2, varscan2
- ANK3 | c.10064C>A p.S3355Y | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as COSV55058702; called by muse, mutect2, varscan2
- ANKRD30A | c.1337G>A p.R446K (on ENST00000611781; = p.R390K on NM_052997.2) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as COSV64610683; called by muse, mutect2, varscan2
- ANKS1B | c.3664A>T p.K1222* (on ENST00000547776 / NM_152788.4; = p.K388* on NM_020140.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV59119369; called by muse, mutect2, varscan2
- ANO4 | c.1396G>A p.E466K (on ENST00000392977 / NM_001286615.2; = p.E431K on NM_178826.4) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV54593435; called by muse, mutect2, varscan2
- APBA1 | c.2446C>T p.H816Y | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV55228315; called by muse, mutect2, varscan2
- APBB1IP | c.981G>A p.W327* | Nonsense Mutation (SNP) | VAF 59/152 reads (39%) | catalogued as COSV66132592; called by muse, mutect2, varscan2
- ARGFX | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV57682361; called by muse, mutect2, varscan2
- ARHGAP15 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.304); catalogued as rs201268929, COSV54496728; called by muse, mutect2, varscan2
- ARHGAP25 | c.436C>T p.L146F (on ENST00000409202 / NM_001007231.3; = p.L139F on NM_014882.3) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV54902556; called by muse, mutect2, varscan2
- ARHGAP32 | c.3836G>T p.S1279I (on ENST00000310343 / NM_001378025.1; = p.S930I on NM_014715.4) | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as rs1219754029, COSV59848211; called by muse, mutect2, varscan2
- ARHGAP44 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52394421; called by muse, mutect2, varscan2
- ARHGEF12 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs769876465, COSV63104786; called by muse, mutect2, varscan2
- ASAP2 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55632021; called by muse, mutect2, varscan2
- ASIC2 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as COSV63304099, COSV63308057; called by muse, mutect2, varscan2
- ASPA | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53981164; called by muse, mutect2, varscan2
- ASTN2 | c.2032G>A p.G678R (on ENST00000313400 / NM_001365069.1; = p.G627R on NM_014010.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267602103, COSV57765897; called by muse, mutect2, varscan2
- ATP12A | c.2411C>T p.P804L | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54516540; called by muse, mutect2, varscan2
- ATP13A4 | c.2578C>T p.H860Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs868804050, COSV61320332; called by muse, mutect2, varscan2
- ATRNL1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV61796680; called by muse, mutect2, varscan2
- ATRNL1 | c.1517T>G p.V506G | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV61804753; called by muse, mutect2, varscan2
- AUTS2 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV61402172; called by muse, mutect2, varscan2
- BABAM2 | c.1074G>A p.M358I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV59623532; called by muse, mutect2, varscan2
- BCAN | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as COSV61256970; called by muse, mutect2, varscan2
- BCAR1 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50783725; called by muse, mutect2, varscan2
- BEND4 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs1182983064, COSV72468934; called by muse, mutect2, varscan2
- BRD4 | c.1814A>T p.D605V | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV54586394; called by muse, mutect2, varscan2
- BTBD3 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1237891192, COSV54781123, COSV99655857; called by muse, mutect2, varscan2
- BTG1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV55458872; called by muse, mutect2, varscan2
- BTNL2 | c.335A>T p.H112L | Missense Mutation (SNP) | VAF 120/141 reads (85%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV100896094; called by muse, mutect2, varscan2
- BTNL2 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 114/135 reads (84%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100896096; called by muse, varscan2
- C1orf131 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as COSV100009776; called by muse, mutect2, varscan2
- C4orf17 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58511554; called by muse, varscan2
- C6 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as rs868271099, COSV54710507, COSV99667004; called by muse, mutect2, varscan2
- CABP2 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV53708503; called by muse, mutect2, varscan2
- CACNA1D | c.4664G>A p.R1555Q (on ENST00000350061 / NM_001128840.3; = p.R1575Q on NM_000720.4) | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765670623, COSV55445331; called by muse, mutect2, varscan2
- CACNA2D1 | c.2873T>C p.V958A (on ENST00000356253 / NM_001366867.1; = p.V946A on NM_000722.4) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100665436, COSV62380002; called by muse, mutect2, varscan2
- CACNA2D3 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.101); catalogued as rs865798465, COSV55540495; called by muse, mutect2, varscan2
- CACNB4 | c.523A>T p.K175* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as rs1553754777, COSV52394285; called by muse, mutect2, varscan2
- CALCRL | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201789608, COSV66473826; called by muse, mutect2, varscan2
- CAMK1D | c.225G>A p.K75= | Splice Region (SNP) | VAF 167/391 reads (43%) | catalogued as rs1272101877, COSV66611748; called by muse, mutect2, varscan2
- CATSPERB | c.2939G>A p.R980K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV56426765; called by muse, mutect2, varscan2
- CCDC173 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.251); catalogued as rs374078230, COSV71653496; called by muse, mutect2, varscan2
- CCDC73 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs766704457, COSV58798810; called by muse, mutect2, varscan2
- CCDC82 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753336168, COSV53591996; called by muse, mutect2, varscan2
- CCR4 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs745506446, COSV58382354; called by muse, mutect2, varscan2
- CD1C | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 151/311 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV63806515; called by muse, mutect2, varscan2
- CD5L | c.983G>A p.R328K | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as COSV63822018; called by muse, mutect2, varscan2
- CDC42BPG | c.3185G>A p.G1062D | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.831); catalogued as COSV61347460; called by muse, mutect2, varscan2
- CDH10 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.52); PolyPhen benign (0.285); catalogued as COSV52570072; called by muse, mutect2, varscan2
- CDH16 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as COSV55336706, COSV55337272; called by muse, mutect2, varscan2
- CDH4 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV64655352; called by muse, mutect2, varscan2
- CDK8 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV67420836; called by muse, mutect2, varscan2
- CFAP206 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs146287743; called by muse, mutect2, varscan2
- CFAP43 | c.3945G>A p.R1315= | Splice Region (SNP) | VAF 17/36 reads (47%) | catalogued as COSV63853181; called by muse, mutect2, varscan2
- CFAP46 | c.7580G>A p.R2527K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1350076389, COSV54152799; called by muse, mutect2
- CFAP53 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 62/136 reads (46%) | catalogued as COSV68351989; called by muse, mutect2, varscan2
- CFHR3 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66402226; called by muse, mutect2, varscan2
- CFHR4 | c.1024G>A p.E342K (on ENST00000367416 / NM_001201551.2; = p.E96K on NM_006684.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as COSV52228992; called by muse, mutect2, varscan2
- CFTR | c.3263A>G p.N1088S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0.021); catalogued as rs1199667380, COSV50054547; called by muse, mutect2, varscan2
- CHDH | c.680G>A p.W227* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV59457679; called by muse, mutect2, varscan2
- CHMP7 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV57533001; called by muse, mutect2, varscan2
- CHP1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV58157219; called by muse, mutect2, varscan2
- CIB3 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV54166347; called by muse, mutect2, varscan2
- CIZ1 | c.2131G>A p.D711N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs752622423, COSV52971511; called by muse, mutect2, varscan2
- CLIC5 | c.886C>T p.L296F (on ENST00000185206 / NM_001370649.1; = p.L137F on NM_016929.5) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV51759064; called by muse, mutect2, varscan2
- CNGA3 | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV55624543; called by muse, varscan2
- CNGA3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55624555; called by muse, varscan2
- CNGA4 | c.312G>C p.R104S | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV66005165, COSV66005961; called by muse, mutect2, varscan2
- CNGB3 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 121/271 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs772140410, COSV60687848; called by muse, mutect2, varscan2
- CNKSR2 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 43/46 reads (93%) | SIFT tolerated (0.24); PolyPhen benign (0.079); catalogued as COSV54256682; called by muse, mutect2, varscan2
- CNOT1 | c.5672C>T p.T1891I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV55316923; called by muse, mutect2, varscan2
- CNOT1 | c.3209T>A p.I1070N | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV55316933; called by muse, mutect2, varscan2
- CNTN4 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61873377; called by muse, mutect2, varscan2
- CNTN5 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as rs1385144818, COSV54282815, COSV99680319; called by muse, mutect2, varscan2
- COBL | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99472717; called by muse, mutect2, varscan2
- COL1A2 | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51958279; called by muse, mutect2, varscan2
- COL21A1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55161750; called by muse, mutect2, varscan2
- COL27A1 | c.5537C>T p.S1846L | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV61926318; called by muse, mutect2, varscan2
- COL3A1 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58586663; called by muse, mutect2, varscan2
- COL4A2 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64628469; called by muse, mutect2, varscan2
- COL4A5 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as COSV60360760, COSV60362063; called by muse, mutect2, varscan2
- COLEC10 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100250670; called by muse, mutect2, varscan2
- CPA6 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.68); PolyPhen benign (0.406); catalogued as rs1018666393, COSV52719710, COSV52732409; called by muse, mutect2, varscan2
- CPEB1 | c.713C>T p.S238F (on ENST00000617958; = p.S178F on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV55619037; called by muse, mutect2, varscan2
- CPNE9 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV56068524; called by muse, mutect2, varscan2
- CPXM2 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780477883, COSV53859463; called by muse, mutect2, varscan2
- CSMD2 | c.6130C>T p.P2044S | Missense Mutation (SNP) | VAF 80/90 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53914339; called by muse, mutect2, varscan2
- CSMD3 | c.10714G>A p.E3572K (on ENST00000297405 / NM_001363185.1; = p.E3403K on NM_052900.3) | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as rs1471973275, COSV52139070, COSV52186456; called by muse, mutect2, varscan2
- CSMD3 | c.8815C>T p.P2939S (on ENST00000297405 / NM_001363185.1; = p.P2770S on NM_052900.3) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV52186479, COSV99838633; called by muse, mutect2, varscan2
- CTNND2 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV58890469; called by muse, mutect2, varscan2
- CUX2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55632809; called by muse, mutect2, varscan2
- CWF19L1 | c.505-1G>A p.X169_splice | Splice Site (SNP) | VAF 33/76 reads (43%) | catalogued as COSV62499307; called by muse, mutect2, varscan2
- CXCR1 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV55280937; called by muse, mutect2, varscan2
- CXorf66 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 128/140 reads (91%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65169267; called by muse, mutect2, varscan2
- CYP2A13 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as COSV57837943; called by muse, mutect2, varscan2
- DAAM1 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.456); catalogued as rs770212276, COSV62836469; called by muse, mutect2, varscan2
- DBR1 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 236/541 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53429866; called by muse, mutect2, varscan2
- DBX2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1289926808, COSV60337792; called by muse, mutect2
- DCC | c.4052C>T p.P1351L | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs751059155, COSV71432556; called by muse, varscan2
- DCHS1 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as COSV55035883; called by muse, mutect2, varscan2
- DCSTAMP | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as rs377712228; called by muse, mutect2, varscan2
- DDIT3 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56254885; called by muse, mutect2, varscan2
- DEF6 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57354100; called by muse, mutect2, varscan2
- DHRS7C | c.503C>T p.S168F (on ENST00000330255 / NM_001220493.2; = p.S167F on NM_001105571.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57650883; called by muse, mutect2, varscan2
- DHTKD1 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 86/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53803782; called by muse, mutect2, varscan2
- DKK3 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1045241569, COSV58868776; called by muse, mutect2, varscan2
- DMBT1 | c.7514G>A p.R2505Q (on ENST00000338354 / NM_001377530.1; = p.R1748Q on NM_004406.3) | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.154); catalogued as rs537234062, COSV57532912; called by muse, mutect2, varscan2
- DMRT3 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.073); catalogued as COSV51904654; called by muse, mutect2, varscan2
- DNAH12 | c.1173G>A p.W391* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV60857089; called by muse, mutect2, varscan2
- DNAH17 | c.9841C>T p.R3281W | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1256951615, COSV101102385, COSV101102940; called by muse, mutect2
- DNAH7 | c.6295C>T p.R2099* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as rs1489692267, COSV56765894; called by muse, mutect2, varscan2
- DNAH8 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 44/54 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV59447161; called by muse, mutect2, varscan2
- DNAH8 | c.3204G>A p.M1068I | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1259181793, COSV59447188; called by muse, mutect2, varscan2
- DNAH9 | c.8593G>A p.A2865T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV52350502; called by muse, mutect2, varscan2
- DNAJC5G | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs758282251, COSV56080095; called by muse, mutect2, varscan2
- DOCK3 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56522532; called by muse, mutect2, varscan2
- DPF1 | c.538C>T p.L180F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV100831490; called by muse, mutect2, varscan2
- DPY19L4 | c.2087C>T p.P696L | Missense Mutation (SNP) | VAF 136/380 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV68962920; called by muse, varscan2
- DSCAM | c.2211T>G p.I737M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV68027026; called by muse, mutect2, varscan2
- DSG1 | c.1008C>T p.P336= | Splice Region (SNP) | VAF 8/24 reads (33%) | catalogued as COSV57135503; called by muse, mutect2, varscan2
- DSP | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 120/133 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65792911; called by muse, mutect2, varscan2
- DTNA | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.075); catalogued as COSV52004391; called by muse, mutect2, varscan2
- DUOX2 | c.4555C>T p.P1519S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66532254; called by muse, mutect2, varscan2
- DYNC2H1 | c.6775A>C p.T2259P | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as COSV62094620; called by muse, mutect2, varscan2
- E4F1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV57039134; called by muse, mutect2, varscan2
- EEF1A1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.44); catalogued as COSV58549690, COSV58550143; called by muse, mutect2, varscan2
- EGFLAM | c.2686C>T p.L896F (on ENST00000354891 / NM_001205301.2; = p.L888F on NM_152403.4) | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV59303001; called by muse, mutect2, varscan2
- EGFR | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1219568637, COSV51781835; called by muse, mutect2, varscan2
- EIF4G1 | c.1889C>T p.P630L (on ENST00000346169 / NM_198241.3; = p.P434L on NM_004953.5) | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59991104; called by muse, mutect2, varscan2
- ELMO2 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51683097; called by muse, mutect2, varscan2
- ENPP4 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as rs1234067007, COSV58089032; called by muse, mutect2, varscan2
- EP300 | c.4859C>T p.P1620L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV99608622; called by muse, mutect2, varscan2
- EPHA3 | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV60706732; called by muse, mutect2, varscan2
- EPHA7 | c.2560C>T p.R854C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465960814, COSV65178482; called by muse, mutect2, varscan2
- EPHB1 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67662008; called by muse, mutect2, varscan2
- EPHB3 | c.2363C>T p.S788F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs146519815, COSV57809180; called by muse, mutect2, varscan2
- EPOR | c.911T>C p.F304S | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55800349; called by muse, mutect2, varscan2
- ERICH3 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.106); catalogued as rs1319580691, COSV58607146; called by muse, mutect2, varscan2
- ERO1A | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); catalogued as rs779201951, COSV67471214; called by muse, mutect2, varscan2
- ESS2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52817063; called by muse, mutect2, varscan2
- ETS2 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 132/317 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.305); catalogued as COSV62872991; called by muse, mutect2, varscan2
- EXOC3L2 | c.2035C>T p.H679Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV99374532; called by muse, mutect2, varscan2
- FAAP20 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV101052000; called by muse, varscan2
- FAH | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55720523, COSV55721199; called by muse, mutect2, varscan2
- FAM177B | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV62601137; called by muse, mutect2, varscan2
- FAM189B | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63219255; called by muse, mutect2, varscan2
- FAM3B | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV63613184; called by muse, mutect2, varscan2
- FAM47B | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV61454002; called by muse, mutect2, varscan2
- FAM53C | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV53511645; called by muse, mutect2, varscan2
- FANK1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs770914661, COSV64156223; called by muse, mutect2, varscan2
- FASLG | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV60680176; called by muse, mutect2, varscan2
- FAT3 | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53113497; called by muse, mutect2, varscan2
- FAT3 | c.4568G>A p.R1523K | Missense Mutation (SNP) | VAF 171/495 reads (35%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.608); catalogued as COSV53113521; called by muse, mutect2, varscan2
- FAT4 | c.4141G>A p.E1381K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs747192883, COSV67887111; called by muse, mutect2, varscan2
- FAT4 | c.6022C>T p.R2008W | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58671195; called by muse, mutect2, varscan2
- FAT4 | c.10265G>A p.G3422E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58686395; called by muse, mutect2, varscan2
- FBN2 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs1234305134, COSV52514633; called by muse, mutect2, varscan2
- FBXL4 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV100014133; called by muse, mutect2, varscan2
- FKBP5 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 72/76 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61881786; called by muse, mutect2, varscan2
- FKBP5 | c.92G>A p.R31K | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV61881791; called by muse, mutect2, varscan2
- FNDC3B | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.596); catalogued as COSV61042608; called by muse, mutect2, varscan2
- FOCAD | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 46/57 reads (81%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV58099443, COSV58099713; called by muse, mutect2, varscan2
- FOXC2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV57443975; called by muse, mutect2, varscan2
- FOXRED2 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as rs775500624, COSV53399783; called by muse, mutect2
- FPR1 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as COSV59052171; called by muse, mutect2, varscan2
- G6PD | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1557230370, COSV100854908, COSV63703240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRA6 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs77320885, COSV50881918; called by muse, mutect2, varscan2
- GAK | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58504901; called by muse, mutect2, varscan2
- GAL3ST1 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.017); catalogued as rs867940591, COSV58892602; called by muse, mutect2, varscan2
- GALNTL6 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV72491083; called by muse, mutect2, varscan2
- GATAD2B | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 69/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64084235; called by muse, mutect2, varscan2
- GDAP2 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 49/56 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs547756474, COSV65612163; called by muse, mutect2, varscan2
- GIGYF2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1276350605, COSV65249633; called by muse, mutect2, varscan2
- GLB1L | c.548T>A p.V183E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850568; called by muse, mutect2, varscan2
- GLB1L | c.547G>A p.V183M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776043562, COSV99850573; called by muse, mutect2, varscan2
- GNL1 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 144/161 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64920999; called by muse, mutect2, varscan2
- GOLM1 | c.389A>T p.N130I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV57414485; called by muse, mutect2, varscan2
- GON4L | c.3916C>T p.P1306S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.343); catalogued as rs775318160, COSV55193989; called by muse, mutect2, varscan2
- GPLD1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 83/95 reads (87%) | SIFT tolerated (0.32); PolyPhen benign (0.022); catalogued as COSV57757224; called by muse, mutect2, varscan2
- GPR37L1 | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561408193, COSV66162327; called by muse, mutect2, varscan2
- GPRC6A | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV59953171; called by muse, mutect2, varscan2
- GRID2 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866806935, COSV56174252; called by muse, mutect2, varscan2
- GRM5 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM138106, COSV59605781, COSV59628660; called by muse, mutect2, varscan2
- GUCY2F | c.2239G>A p.G747S | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.48); PolyPhen benign (0.088); catalogued as COSV54302312; called by muse, mutect2, varscan2
- HABP2 | c.1156C>T p.H386Y | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs886046743, COSV63636756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAO2 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 91/101 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58039678; called by muse, mutect2, varscan2
- HAPLN3 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as rs985815597, COSV61360881; called by muse, mutect2, varscan2
- HDAC3 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 102/126 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59495962; called by muse, mutect2, varscan2
- HEATR4 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs528517201, COSV58569867; called by muse, mutect2, varscan2
- HECTD1 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 28/67 reads (42%) | catalogued as COSV67946403; called by muse, mutect2, varscan2
- HLA-F | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 30/33 reads (91%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.595); catalogued as COSV52575576; called by muse, mutect2, varscan2
- HSPA6 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV59061132; called by muse, mutect2, varscan2
- HTT | c.5105C>T p.S1702F | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV61862472; called by muse, mutect2, varscan2
- IDH3A | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV55112870; called by muse, mutect2, varscan2
- IGDCC3 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771890519, COSV60077636; called by muse, mutect2, varscan2
- IGFL3 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs202054517, COSV58242812; called by muse, mutect2, varscan2
- IGKV1-27 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs1384422044; called by muse, mutect2, varscan2
- IL17RA | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs767275300, COSV60053470; called by muse, mutect2, varscan2
- IL17RE | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 104/265 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs770571811, COSV55968391; called by muse, mutect2, varscan2
- IL1R1 | c.1593G>A p.W531* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV52104585; called by muse, mutect2, varscan2
- IL20RA | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as rs369006457; called by muse, mutect2, varscan2
- IL32 | c.449T>C p.F150S (on ENST00000396890 / NM_001308078.4; = p.F104S on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99145503; called by muse, mutect2, varscan2
- IL5RA | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV56523375; called by muse, mutect2, varscan2
- ILDR2 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 42/99 reads (42%) | catalogued as rs141350747; called by muse, mutect2, varscan2
- ILDR2 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 44/117 reads (38%) | catalogued as COSV54831206; called by muse, mutect2, varscan2
- IMPDH2 | c.1524-2A>G p.X508_splice | Splice Site (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100455053; called by muse, mutect2, varscan2
- INAVA | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.527); catalogued as rs1398436776, COSV66256635; called by muse, mutect2, varscan2
- INHA | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as rs376826452; called by muse, mutect2, varscan2
- INHBB | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54677921; called by muse, mutect2, varscan2
- INO80 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.303); catalogued as rs780868252, COSV62738365; called by muse, mutect2, varscan2
- INPP5D | c.655G>A p.E219K (on ENST00000445964 / NM_001017915.3; = p.E218K on NM_005541.5) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV64036099; called by muse, mutect2, varscan2
- INPPL1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs745317721, COSV99996263; called by muse, mutect2, varscan2
- ITM2A | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64810927; called by muse, mutect2, varscan2
- JHY | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.178); catalogued as COSV56219491; called by muse, mutect2, varscan2
- KALRN | c.3778C>T p.R1260W | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs748339297, COSV53764959, COSV53776572; called by muse, mutect2, varscan2
- KAT14 | c.759A>T p.E253D | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV66607766; called by muse, mutect2, varscan2
- KCNB2 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050367; called by muse, mutect2, varscan2
- KCNC1 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV56394414; called by muse, mutect2, varscan2
- KCNN2 | c.767T>A p.I256N (on ENST00000264773; = p.I468N on NM_021614.4) | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV53288904; called by muse, mutect2, varscan2
- KCNQ2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60434270; called by muse, mutect2, varscan2
- KCTD2 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV59368820; called by muse, mutect2, varscan2
- KEL | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV62334398; called by muse, mutect2, varscan2
- KHDC3L | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs565995615, COSV64869193; called by muse, mutect2, varscan2
- KIF2B | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs267604961, COSV52130745; called by muse, mutect2, varscan2
- KIF4B | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV70529377; called by muse, mutect2, varscan2
- KIR3DL1 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1419823828; called by muse, mutect2, varscan2
- KIR3DL2 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs754134072, COSV54389169; called by muse, mutect2, varscan2
- KLF7 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV100519161; called by muse, mutect2, varscan2
- KLHL13 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV53247730; called by muse, mutect2, varscan2
- KLHL32 | c.1738T>A p.F580I | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV51521301; called by muse, mutect2, varscan2
- KLKB1 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs867707828, COSV52995896; called by muse, mutect2, varscan2
- KMT2C | c.12149C>T p.S4050L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV100070102, COSV51429659, COSV51442169; called by muse, mutect2, varscan2
- KRT35 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55843124; called by muse, mutect2, varscan2
- KRT78 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58851805; called by muse, mutect2, varscan2
- KRT84 | c.590G>A p.W197* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV57771806; called by muse, mutect2, varscan2
- KRT9 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.389); catalogued as rs759302830, COSV55853235, COSV55855613; called by muse, mutect2
- KRTAP5-8 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1196536101, COSV68324595; called by muse, mutect2, varscan2
- L3MBTL3 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV100696456, COSV62386374; called by muse, mutect2, varscan2
- LAMA2 | c.6352G>A p.E2118K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.078); catalogued as rs868446011, COSV70342704; called by muse, mutect2, varscan2
- LCE2B | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64227685; called by muse, mutect2, varscan2
- LCP1 | c.1073G>A p.G358E | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59941096; called by muse, mutect2, varscan2
- LMTK3 | c.2908G>A p.E970K | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs751370624, COSV54312560; called by muse, mutect2, varscan2
- LOXL4 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV53256777; called by muse, mutect2, varscan2
- LPA | c.5179G>A p.G1727R | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as COSV60302330; called by muse, mutect2, varscan2
- LRBA | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV63955902; called by muse, mutect2, varscan2
- LRIG1 | c.2605A>T p.I869F | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV56240359; called by muse, mutect2, varscan2
- LRIG1 | c.2119G>A p.G707R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99833801; called by muse, mutect2, varscan2
- LRP1B | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.845); catalogued as rs745855601, COSV67197634, COSV67202427; called by muse, mutect2, varscan2
- LRRC15 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775383231, COSV61650171; called by muse, varscan2
- LRRC49 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV53011015; called by muse, mutect2, varscan2
- LRRC4C | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs867956688, COSV53426374, COSV53432590; called by muse, mutect2, varscan2
- LRSAM1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1032048507, COSV55940170; called by muse, mutect2, varscan2
- LSAMP | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.241); catalogued as COSV61291290, COSV61291719; called by muse, varscan2
- LYRM1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV54643792; called by muse, mutect2, varscan2
- MAFB | c.662T>A p.V221E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100965047; called by muse, mutect2
- MAFB | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100965048; called by muse, mutect2
- MAGEA10 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 63/80 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV54883932; called by muse, mutect2, varscan2
- MAGEA10 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.81); PolyPhen benign (0.08); catalogued as COSV54883941; called by muse, mutect2, varscan2
- MAGEB16 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67873963; called by mutect2, varscan2
- MAOB | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV65205360; called by muse, mutect2, varscan2
- MATR3 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV63077354; called by muse, mutect2, varscan2
- MBD5 | c.4207T>A p.L1403I | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as COSV68697116; called by muse, mutect2, varscan2
- MCC | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV56729211; called by muse, mutect2, varscan2
- MCF2L2 | c.2924G>A p.G975D | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV61050542; called by muse, mutect2, varscan2
- ME1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as rs780787550, COSV63839355; called by muse, mutect2, varscan2
- MECOM | c.380G>A p.S127N (on ENST00000468789 / NM_001105078.4; = p.S315N on NM_004991.4) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV52964712; called by muse, mutect2, varscan2
- MEIS1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV55486956; called by muse, mutect2, varscan2
- MEIS2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV54936045; called by muse, mutect2, varscan2
- MEP1A | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV57919946; called by muse, mutect2, varscan2
- MGA | c.3463C>T p.R1155* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as rs528009988, COSV54948941; called by muse, mutect2, varscan2
- MGA | c.6178C>T p.Q2060* (on ENST00000219905 / NM_001164273.1; = p.Q1851* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 44/111 reads (40%) | catalogued as COSV54954245; called by muse, mutect2, varscan2
- MGAM | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866353991, COSV72074697; called by muse, mutect2, varscan2
- MGAT3 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as COSV57865566; called by muse, mutect2, varscan2
- MISP | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.048); catalogued as COSV53120315; called by muse, mutect2, varscan2
- MMP1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1244984719, COSV59510456; called by muse, mutect2, varscan2
- MMP26 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV56171303; called by muse, mutect2, varscan2
- MON1A | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV56560614; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1754C>T p.S585F | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56620036; called by muse, mutect2, varscan2
- MRGBP | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65111447; called by muse, mutect2, varscan2
- MTNR1A | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs150190540, COSV56155172; called by muse, mutect2, varscan2
- MUC16 | c.22417C>T p.P7473S | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.818); catalogued as COSV67457303; called by muse, mutect2, varscan2
- MUC16 | c.12273G>A p.M4091I | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV67447314, COSV67479700; called by muse, mutect2, varscan2
- MUC16 | c.9637G>A p.E3213K | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs865897685, COSV101197664, COSV67467593; called by muse, mutect2, varscan2
- MYF6 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV57351920; called by muse, mutect2, varscan2
- MYH1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780763560, COSV56843727, COSV56851492; called by muse, mutect2, varscan2
- MYH2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV55435896; called by muse, mutect2, varscan2
- MYH3 | c.5317G>A p.E1773K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV56865176; called by muse, mutect2, varscan2
- MYH4 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199837494, COSV55116468; called by muse, mutect2, varscan2
- MYH7 | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM115864, COSV100806144; called by muse, mutect2, varscan2
- MYH7 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100806073, COSV62519471; called by muse, mutect2, varscan2
- MYOM1 | c.3968G>A p.G1323E | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55292138; called by muse, mutect2, varscan2
- NAALAD2 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as rs774344509, COSV58961287; called by muse, mutect2, varscan2
- NAPEPLD | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV58522348; called by muse, mutect2, varscan2
- NBEA | c.6263C>T p.S2088F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59786104; called by muse, mutect2, varscan2
- NBPF3 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.375); catalogued as rs1428207199; called by mutect2, varscan2
- NCAM1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV57516708; called by muse, mutect2
- NCKAP1L | c.859G>A p.G287S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV53207048; called by muse, mutect2, varscan2
- NCKAP5 | c.5285C>T p.S1762F | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV58444805, COSV58472805; called by muse, mutect2, varscan2
- NDRG1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as COSV60484033; called by muse, mutect2, varscan2
- NEB | c.9639G>A p.W3213* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV51418489; called by muse, mutect2
- NEBL | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1269179367, COSV65799546; called by muse, mutect2, varscan2
- NEDD9 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV65158914; called by muse, mutect2, varscan2
- NES | c.3164C>A p.A1055D | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV63961142; called by muse, mutect2, varscan2
- NEURL3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV60440675; called by muse, mutect2, varscan2
- NF1 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV100647130; called by muse, mutect2, varscan2
- NFKB1 | c.2800C>T p.R934C (on ENST00000394820 / NM_001382627.1; = p.R935C on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as rs200653734, COSV56956675; called by muse, mutect2, varscan2
- NID1 | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV51620627, COSV99937738; called by muse, mutect2, varscan2
- NIT2 | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67630402; called by muse, mutect2, varscan2
- NLGN4X | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.229); catalogued as rs747105471, COSV52018997, COSV52029218; called by muse, mutect2, varscan2
- NLK | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV69408915; called by muse, mutect2, varscan2
- NLRC5 | c.4288C>T p.R1430C | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.424); catalogued as rs557005239, COSV52648240; called by muse, mutect2, varscan2
- NLRP13 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.484); catalogued as COSV61621893, COSV61622630; called by muse, mutect2, varscan2
- NMBR | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs755000490, COSV57801305; called by muse, mutect2, varscan2
- NOB1 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 23/46 reads (50%) | catalogued as COSV52061733; called by muse, mutect2, varscan2
- NOVA1 | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57477342, COSV57477597, COSV99946718; called by muse, mutect2, varscan2
- NPAS2 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as COSV59557923; called by muse, mutect2, varscan2
- NR1H2 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs377003047; called by muse, mutect2, varscan2
- NR1I3 | c.856G>A p.D286N (on ENST00000367982 / NM_001077480.3; = p.D282N on NM_005122.5) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV63468039; called by muse, mutect2, varscan2
- NR3C2 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as CM070225, COSV60990849; called by muse, mutect2, varscan2
- NRBP1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV51994291; called by muse, mutect2, varscan2
- NTRK1 | c.1982G>A p.G661E | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV62325756; called by muse, mutect2, varscan2
- NTRK2 | c.2388G>A p.M796I (on ENST00000323115 / NM_001369534.1; = p.M812I on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs758574086, COSV52864658; called by muse, mutect2, varscan2
- NUP210 | c.3700C>T p.P1234S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54406607; called by muse, mutect2, varscan2
- NUP210L | c.4021G>A p.E1341K | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV55148113; called by muse, mutect2, varscan2
- NUP210L | c.3842A>T p.E1281V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99668134; called by muse, mutect2, varscan2
- NUP210L | c.3841G>A p.E1281K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99668139; called by muse, mutect2, varscan2
- NUP98 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV61432352; called by muse, mutect2, varscan2
- NWD1 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 106/235 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs568405169, COSV60339667; called by muse, mutect2, varscan2
- NXPH1 | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV68314827; called by muse, mutect2, varscan2
- OIT3 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs775669343, COSV61826181; called by muse, mutect2, varscan2
- OR10A2 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.767); catalogued as COSV56299371; called by muse, mutect2, varscan2
- OR10H2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV59945601; called by muse, mutect2, varscan2
- OR13C2 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 53/96 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV73377649; called by muse, mutect2, varscan2
- OR13C8 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58611235; called by muse, mutect2, varscan2
- OR13D1 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV59513528, COSV59515030; called by muse, mutect2, varscan2
- OR14A16 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as COSV62926428; called by muse, mutect2, varscan2
- OR14C36 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV58601364; called by muse, mutect2, varscan2
- OR14K1 | c.912G>A p.W304* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99315219; called by muse, mutect2, varscan2
- OR1K1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315769885, COSV52956550; called by muse, mutect2, varscan2
- OR2L2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs914168723, COSV63552073; called by muse, mutect2, varscan2
- OR4C13 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as rs190982976, COSV73648668; called by muse, mutect2, varscan2
- OR4K13 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59859697; called by muse, mutect2, varscan2
- OR51G1 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV58969315; called by muse, mutect2, varscan2
- OR51I1 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV66507955; called by muse, mutect2, varscan2
- OR51T1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59025557, COSV59026954; called by muse, mutect2, varscan2
- OR52E6 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV61432136; called by muse, mutect2
- OR52J3 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66746307, COSV66746315; called by muse, mutect2, varscan2
- OR5H15 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs377308175, COSV62947393; called by muse, mutect2, varscan2
- OR5H15 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV62948063; called by muse, mutect2, varscan2
- OR5T1 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100479281, COSV57302779; called by muse, mutect2, varscan2
- OR7E24 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV71702224; called by muse, mutect2, varscan2
- OR8K5 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); catalogued as COSV57889134; called by muse, mutect2, varscan2
- OR8S1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as COSV59599902; called by muse, mutect2, varscan2
- OR8S1 | c.951G>A p.W317* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV59599908; called by muse, mutect2, varscan2
- OR9A4 | c.466C>T p.Q156* | Nonsense Mutation (SNP) | VAF 69/159 reads (43%) | catalogued as rs782594459, COSV71885022; called by muse, mutect2, varscan2
- OR9K2 | c.748G>A p.V250I (on ENST00000305377; = p.V228I on NM_001005243.1) | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.437); catalogued as COSV59532055; called by muse, mutect2, varscan2
- OSBP2 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV60243190; called by muse, mutect2, varscan2
- OTOGL | c.6439G>A p.E2147K (on ENST00000547103; = p.E2138K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.8); PolyPhen benign (0.43); catalogued as rs267603695, COSV54016960; called by muse, mutect2, varscan2
- OTOL1 | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as rs1220850500, COSV60006791; called by muse, mutect2, varscan2
- PAPLN | c.1687C>T p.P563S (on ENST00000554301; = p.P536S on NM_173462.4) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.186); catalogued as COSV53718062; called by muse, mutect2, varscan2
- PAPPA | c.440T>A p.I147N | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60283770; called by muse, mutect2, varscan2
- PAPPA | c.4843G>A p.E1615K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1484926492, COSV60283780; called by muse, mutect2, varscan2
- PARP14 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.162); catalogued as COSV71734722; called by muse, mutect2, varscan2
- PARP15 | c.1544G>A p.R515Q (on ENST00000464300 / NM_001113523.3; = p.R281Q on NM_152615.2) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745329291, COSV59971529; called by muse, mutect2, varscan2
- PARP9 | c.156G>A p.E52= | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as COSV64450724; called by muse, mutect2, varscan2
- PBRM1 | c.3185G>A p.R1062Q (on ENST00000296302 / NM_001366071.2; = p.R1037Q on NM_018313.5) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757754297, COSV56260834; called by muse, mutect2, varscan2
- PCDH15 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV100224442, COSV57314634; called by muse, mutect2, varscan2
- PCDHA5 | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65352573; called by muse, mutect2, varscan2
- PCDHB4 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as rs140862802, COSV52022703; called by muse, mutect2, varscan2
- PCDHB6 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV50689664; called by muse, mutect2, varscan2
- PCDHB7 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.991); catalogued as COSV50769553; called by muse, mutect2, varscan2
- PCDHGA9 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs964616167, COSV53943996; called by muse, mutect2, varscan2
- PCLO | c.14471C>T p.P4824L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1437232168, COSV61627999; called by muse, mutect2, varscan2
- PCLO | c.10876C>T p.P3626S | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61636468; called by muse, mutect2, varscan2
- PCLO | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV61636478; called by muse, mutect2, varscan2
- PCNX1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV53095055; called by muse, mutect2, varscan2
- PDGFRL | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52412324; called by muse, mutect2, varscan2
- PDHX | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57165312; called by muse, mutect2, varscan2
- PDZD3 | c.1396C>T p.R466* (on ENST00000531114; = p.R386* on NM_024791.4) | Nonsense Mutation (SNP) | VAF 43/92 reads (47%) | catalogued as rs746195046, COSV52704499, COSV52709382; called by muse, mutect2, varscan2
- PGLYRP4 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs147105602, COSV62835747; called by muse, mutect2, varscan2
- PGM5 | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | catalogued as COSV67163741, COSV67163853; called by muse, mutect2, varscan2
- PHACTR1 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 229/261 reads (88%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.025); catalogued as COSV60667510; called by muse, mutect2, varscan2
- PHLDB2 | c.2279C>T p.S760F (on ENST00000393925 / NM_001134439.2; = p.S717F on NM_145753.2) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV67311281; called by muse, mutect2, varscan2
- PHLPP1 | c.4163C>T p.A1388V | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs750847498, COSV53029103; called by muse, mutect2, varscan2
- PHYHIPL | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV53248759; called by muse, mutect2, varscan2
- PICALM | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as COSV62670916; called by muse, mutect2, varscan2
- PIGR | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.957); catalogued as COSV62904065; called by muse, mutect2, varscan2
- PIK3R4 | c.1156C>A p.L386I | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV63240955; called by muse, mutect2, varscan2
- PIKFYVE | c.2947C>T p.P983S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs761458286, COSV52241491; called by muse, mutect2, varscan2
- PKHD1L1 | c.8581G>A p.D2861N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.417); catalogued as COSV65743428; called by muse, mutect2, varscan2
- PLCB1 | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62051808; called by muse, mutect2, varscan2
- PLCB4 | c.2627G>A p.G876E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs866533934, COSV53796419; called by muse, mutect2, varscan2
- PLEKHG6 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50600977; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1554865955, COSV62611897; called by muse, mutect2, varscan2
- POLG2 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73347017; called by muse, mutect2, varscan2
- POLL | c.377A>T p.D126V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV54575327; called by muse, mutect2, varscan2
- POLR1A | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.398); catalogued as rs778313125, COSV55693289; called by muse, mutect2, varscan2
- POP4 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs547007300, COSV55676493; called by muse, mutect2, varscan2
- PPP1R3A | c.2654T>C p.V885A | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as COSV52883004; called by muse, mutect2, varscan2
- PREX2 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV55771233; called by muse, mutect2, varscan2
- PRF1 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1278094424, CM1510968, COSV100942613; called by muse, mutect2
- PRF1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.347); catalogued as COSV100942614; called by muse, mutect2, varscan2
- PRKACA | c.590G>T p.W197L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV58066649, COSV58067981; called by muse, mutect2, varscan2
- PRKAG3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV52103027, COSV99291961; called by muse, mutect2, varscan2
- PROS1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.079); catalogued as CM163618, COSV67775415; called by muse, mutect2, varscan2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRSS35 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV63800612; called by muse, mutect2, varscan2
- PRSS48 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV71613855; called by muse, mutect2, varscan2
- PRX | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52530106; called by muse, mutect2, varscan2
- PSG3 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 77/198 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as rs1318786794, COSV59504429; called by muse, varscan2
- PSG9 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52485163; called by muse, mutect2, varscan2
- PSMA8 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV57602652; called by muse, mutect2, varscan2
- PTCHD4 | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV59785042; called by muse, mutect2, varscan2
- PTGIS | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.141); catalogued as rs780217825, COSV54834834; called by muse, mutect2, varscan2
- PTPN13 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770308424, COSV57407038; called by muse, varscan2
- PTPN3 | c.2339C>T p.T780I | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV52706095; called by muse, mutect2, varscan2
- PTPRD | c.5687C>T p.S1896F | Missense Mutation (SNP) | VAF 69/82 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV61938102; called by muse, mutect2, varscan2
- RAB40A | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1480170686, COSV100420937; called by muse, mutect2, varscan2
- RABL6 | c.341T>G p.L114* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as COSV61035714; called by muse, mutect2, varscan2
- RALGDS | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs768745857, COSV64427331; called by muse, mutect2, varscan2
- RALY | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1328305275, COSV99865834; called by muse, mutect2, varscan2
- RANBP2 | c.4895C>T p.P1632L | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV51697715; called by muse, varscan2
- RAVER1 | c.967G>T p.G323* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV53345615; called by muse, mutect2, varscan2
- RBM25 | c.2392G>A p.V798I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.818); catalogued as rs755097869, COSV56200122; called by muse, mutect2
- REG3A | c.461-1G>A p.X154_splice | Splice Site (SNP) | VAF 21/51 reads (41%) | catalogued as COSV59408328, COSV59410858; called by muse, mutect2, varscan2
- RELCH | c.1409T>A p.L470Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV56885852; called by muse, mutect2, varscan2
- RFX6 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.079); catalogued as COSV60585131; called by muse, mutect2, varscan2
- RNF150 | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); catalogued as COSV60790913; called by muse, mutect2, varscan2
- RP1 | c.5859G>A p.M1953I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV55115012; called by muse, mutect2, varscan2
- RPA4 | c.161T>A p.L54H | Missense Mutation (SNP) | VAF 39/42 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61270611; called by muse, mutect2, varscan2
- RPS6KA1 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.335); catalogued as rs757381704, COSV64809987; called by muse, mutect2, varscan2
- RPS6KB2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.978); catalogued as COSV57050189; called by muse, mutect2, varscan2
- RPTN | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 187/427 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768986867, COSV60166732; called by muse, mutect2, varscan2
- RPTN | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 331/788 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV60166714; called by muse, mutect2, varscan2
- RTL3 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV58184215; called by muse, mutect2, varscan2
- RYR2 | c.12958G>A p.E4320K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1409819668, COSV63686403; called by muse, mutect2, varscan2
- SALL1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs763206883, COSV51754165; called by muse, mutect2, varscan2
- SALL4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs200440024, COSV53852420; called by muse, mutect2, varscan2
- SAMD7 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV59417225; called by muse, mutect2, varscan2
- SCIN | c.1115C>T p.P372L (on ENST00000297029 / NM_001112706.3; = p.P125L on NM_033128.3) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV51692919; called by muse, mutect2
- SCN10A | c.5345G>A p.R1782Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs267599796, COSV71860696; called by muse, mutect2, varscan2
- SCN11A | c.3064+2T>A p.X1022_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100181628; called by muse, varscan2
- SCN11A | c.3064+1G>A p.X1022_splice | Splice Site (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100181630, COSV100182811; called by muse, mutect2, varscan2
- SCN11A | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0.233); catalogued as COSV56570653; called by muse, mutect2, varscan2
- SCN1A | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs769582667, COSV57660030; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN3A | c.4767G>A p.W1589* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as rs267598953, COSV51810448, COSV99328961; called by muse, mutect2, varscan2
- SCN5A | c.5394G>A p.W1798* (on ENST00000333535 / NM_198056.3; = p.W1797* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 34/62 reads (55%) | catalogued as COSV61124761; called by muse, mutect2, varscan2
- SCN9A | c.2227G>A p.D743N (on ENST00000303354; = p.D732N on NM_002977.3) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57610569; called by muse, mutect2, varscan2
- SDK1 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67359647; called by muse, mutect2, varscan2
- SDK1 | c.2861C>T p.P954L | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101269392; called by muse, mutect2, varscan2
- SEC14L1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66722393; called by muse, mutect2, varscan2
- SEC16B | c.1733C>T p.T578I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs758435383, COSV57625898; called by muse, mutect2, varscan2
- SERPINA3 | c.547T>A p.Y183N | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67586187; called by muse, mutect2, varscan2
- SERPINB3 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.217); catalogued as COSV52191055; called by muse, mutect2, varscan2
- SERTAD4 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.121); catalogued as COSV65399408; called by muse, mutect2, varscan2
- SESN3 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.767); catalogued as COSV53585050; called by muse, mutect2, varscan2
- SFRP2 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV56837615; called by muse, mutect2, varscan2
- SHFL | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV53462416; called by muse, mutect2, varscan2
- SHISAL1 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV66987997; called by muse, mutect2, varscan2
- SIGLEC12 | c.1616C>T p.S539F (on ENST00000291707 / NM_053003.4; = p.S421F on NM_033329.2) | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.619); catalogued as COSV52461696; called by muse, mutect2, varscan2
- SIN3B | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV56133431; called by muse, mutect2, varscan2
- SIRPB2 | c.586G>A p.G196R | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63123828; called by muse, mutect2, varscan2
- SLC13A5 | c.1578G>A p.V526= | Splice Region (SNP) | VAF 23/56 reads (41%) | catalogued as COSV53423201; called by muse, mutect2, varscan2
- SLC14A1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552191196, COSV58931576; called by muse, mutect2, varscan2
- SLC22A15 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65678116; called by muse, mutect2, varscan2
- SLC22A25 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.445); catalogued as COSV60596106; called by muse, mutect2, varscan2
- SLC26A7 | c.1313G>A p.W438* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV52593819, COSV99404644; called by muse, mutect2, varscan2
- SLC27A5 | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54019745; called by muse, mutect2, varscan2
- SLC2A1 | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV65287503; called by muse, mutect2, varscan2
- SLC38A10 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs749822314, COSV66101495; called by muse, mutect2, varscan2
- SLC44A5 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV63765317; called by muse, mutect2, varscan2
- SLC4A3 | c.1979C>T p.S660F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV56093963; called by muse, mutect2, varscan2
- SLC6A19 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV58671407; called by muse, mutect2, varscan2
- SLC6A20 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62071308; called by muse, mutect2, varscan2
- SLC9C2 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs537127323, COSV62945750; called by muse, mutect2, varscan2
- SLCO1A2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56598935, COSV56605393; called by muse, mutect2, varscan2
- SLFN13 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.992); catalogued as COSV53193599, COSV53194816; called by muse, mutect2, varscan2
- SLIT1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 168/365 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV56589570; called by muse, mutect2, varscan2
- SLITRK5 | c.1341G>A p.M447I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV61523021; called by muse, mutect2, varscan2
- SNAP91 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as rs947796597, COSV52116300, COSV52129558, COSV99056320; called by muse, mutect2, varscan2
- SNAP91 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs376878292, COSV52123521; called by muse, mutect2, varscan2
- SNPH | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV60589449; called by muse, mutect2, varscan2
- SORL1 | c.1532G>A p.G511E | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52749618; called by muse, mutect2, varscan2
- SORL1 | c.1967C>T p.P656L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as rs369728801; called by muse, mutect2, varscan2
- SPANXN3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.991); catalogued as COSV65140359; called by muse, mutect2, varscan2
- SPATA17 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs777481856, COSV65122081; called by muse, mutect2, varscan2
- SPCS2 | c.451A>G p.M151V | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV55227123; called by muse, mutect2, varscan2
- SPOCK3 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs1211547956, COSV62724971; called by muse, mutect2, varscan2
- SREK1 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as COSV52332943; called by muse, mutect2, varscan2
- SRL | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.063); catalogued as COSV68423405; called by muse, mutect2, varscan2
- SRL | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101281339; called by muse, mutect2, varscan2
- SRRT | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV53817675; called by muse, mutect2, varscan2
- ST14 | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV53832662; called by muse, mutect2, varscan2
- STAB1 | c.6466A>G p.N2156D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58736513; called by muse, mutect2, varscan2
- STAB2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 38/83 reads (46%) | catalogued as rs202064459, COSV66336983; called by muse, mutect2, varscan2
- STAB2 | c.6230G>A p.G2077E | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66339329; called by muse, mutect2, varscan2
- STK36 | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV55326721; called by muse, mutect2, varscan2
- SYNE2 | c.15251C>T p.S5084F | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as COSV59951660; called by muse, mutect2, varscan2
- SYPL1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV50578912; called by muse, mutect2, varscan2
- SYT15 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs782508150, COSV65431833; called by muse, mutect2, varscan2
- SYT16 | c.1578G>A p.M526I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1453105434, COSV70856780; called by muse, mutect2, varscan2
- TACC2 | c.5527G>A p.D1843N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV57756391; called by muse, mutect2, varscan2
- TBXAS1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1416520013, COSV54945680; called by muse, mutect2, varscan2
- TCERG1 | c.2371A>G p.R791G | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV57037342; called by muse, mutect2, varscan2
- TDRKH | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV64316338; called by muse, mutect2, varscan2
- TECTA | c.4286C>T p.S1429F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.354); catalogued as COSV50710693; called by muse, mutect2
- TENM3 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV69308692; called by muse, mutect2, varscan2
- TENT5C | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65616035; called by muse, mutect2, varscan2
- TEX13A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV61150563, COSV61158492; called by muse, mutect2, varscan2
- TFB1M | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.241); catalogued as COSV65699160; called by muse, mutect2, varscan2
- TG | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV55076537; called by muse, mutect2, varscan2
- THEMIS | c.955T>G p.L319V | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64071262; called by muse, mutect2, varscan2
- THOC7 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV55733469; called by muse, mutect2, varscan2
- TIMELESS | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV57511616; called by muse, mutect2, varscan2
- TJP3 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs181931412; called by muse, mutect2, varscan2
- TLR3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as rs144550375; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLR4 | c.884A>G p.Y295C (on ENST00000355622 / NM_138554.5; = p.Y255C on NM_003266.4) | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1486520606, COSV62923314; called by muse, mutect2, varscan2
- TMEM132D | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs546922206, COSV101242874, COSV67160502; called by muse, mutect2, varscan2
- TMEM179 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58795443, COSV58796532; called by muse, mutect2, varscan2
- TMEM67 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV60039657; called by muse, mutect2, varscan2
- TMPRSS11E | c.658A>C p.T220P | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1347538895, COSV59519156, COSV59521580; called by muse, varscan2
- TMPRSS6 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs945227319, COSV60978448; called by muse, mutect2, varscan2
- TNFRSF14 | c.789C>G p.D263E | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV63186752; called by muse, mutect2, varscan2
- TNFSF4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV56056577; called by muse, mutect2, varscan2
- TNNI3K | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 64/71 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58548961; called by muse, mutect2, varscan2
- TP53I13 | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV56402567; called by muse, mutect2, varscan2
- TPTE2 | c.1486G>A p.E496K (on ENST00000400230 / NM_199254.2; = p.E419K on NM_130785.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV55021593; called by muse, mutect2, varscan2
- TPTE2 | c.733C>T p.P245S (on ENST00000400230 / NM_199254.2; = p.P168S on NM_130785.3) | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV55021608; called by muse, mutect2, varscan2
- TRAF5 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54822610; called by muse, mutect2, varscan2
- TRHDE | c.1897C>T p.Q633* | Nonsense Mutation (SNP) | VAF 53/106 reads (50%) | catalogued as COSV53843941; called by muse, mutect2, varscan2
- TRIM42 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs754221344, COSV53883139; called by muse, varscan2
- TRIOBP | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.48); catalogued as COSV60377796; called by muse, mutect2, varscan2
- TRPC5 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV53291011; called by muse, mutect2, varscan2
- TRPM6 | c.4816G>A p.D1606N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.036); catalogued as COSV62510737; called by muse, mutect2, varscan2
- TRPM6 | c.3890G>A p.R1297K | Missense Mutation (SNP) | VAF 72/168 reads (43%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1440851175, COSV62507013, COSV62510751; called by muse, mutect2, varscan2
- TRPV6 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.119); catalogued as COSV63891866; called by muse, mutect2, varscan2
- TSHZ2 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs930326171, COSV61587378, COSV61590906; called by muse, mutect2, varscan2
- TSHZ2 | c.1601G>A p.G534E | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61588273; called by muse, mutect2, varscan2
- TSKS | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567740680, COSV55872583; called by muse, mutect2, varscan2
- TSPAN12 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as rs267601247, COSV56079827; called by muse, mutect2, varscan2
- TSPAN13 | c.543C>T p.I181= | Splice Region (SNP) | VAF 38/89 reads (43%) | catalogued as COSV50438213; called by muse, mutect2, varscan2
- TSSK6 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV53063795; called by muse, mutect2, varscan2
- TTBK1 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); catalogued as rs752976145, COSV52491486; called by muse, mutect2, varscan2
- TTBK2 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99141731; called by muse, mutect2, varscan2
- TTBK2 | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); catalogued as rs752644926, COSV99141734; called by muse, mutect2, varscan2
- TTLL2 | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV53443989; called by muse, mutect2, varscan2
- TTN | c.78749G>A p.G26250D (on ENST00000591111; = p.G18826D on NM_003319.4) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | PolyPhen probably damaging (1); catalogued as rs1184831372, COSV60076124; called by muse, mutect2, varscan2
- TTN | c.58168G>A p.D19390N (on ENST00000591111; = p.D11966N on NM_003319.4) | Missense Mutation (SNP) | VAF 84/218 reads (39%) | PolyPhen benign (0); catalogued as COSV60076163; called by muse, mutect2, varscan2
- TTN | c.49090A>T p.T16364S (on ENST00000591111; = p.T8940S on NM_003319.4) | Missense Mutation (SNP) | VAF 28/52 reads (54%) | PolyPhen benign (0.022); catalogued as COSV60076200; called by muse, mutect2, varscan2
- TTN | c.46318C>T p.H15440Y (on ENST00000591111; = p.H8016Y on NM_003319.4) | Missense Mutation (SNP) | VAF 78/179 reads (44%) | PolyPhen probably damaging (0.909); catalogued as rs267599048, COSV60076235; called by muse, mutect2, varscan2
- UBASH3A | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs763399326, COSV52312700; called by mutect2, varscan2
- UBE3A | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51665308; called by muse, mutect2, varscan2
- UBE4B | c.2137C>T p.H713Y (on ENST00000343090 / NM_001105562.3; = p.H584Y on NM_006048.5) | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV53532840; called by muse, mutect2, varscan2
- UGT2B28 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV59432192; called by muse, mutect2, varscan2
- UGT2B4 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59317459; called by muse, mutect2, varscan2
- UHMK1 | c.1025-2A>G p.X342_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV56420139; called by muse, varscan2
- UNC5C | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV71659671; called by muse, mutect2, varscan2
- UNC79 | c.4939G>A p.E1647K (on ENST00000393151 / NM_001346218.2; = p.E1470K on NM_020818.5) | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV56371866; called by muse, mutect2, varscan2
- USP29 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as COSV54142908, COSV99518228; called by muse, mutect2, varscan2
- USP4 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs779718898, COSV55537205; called by muse, mutect2, varscan2
- UTP20 | c.3760G>A p.D1254N | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs967879803, COSV55377554; called by muse, mutect2, varscan2
- VCAN | c.6294G>A p.W2098* | Nonsense Mutation (SNP) | VAF 30/37 reads (81%) | catalogued as COSV54105532; called by muse, mutect2, varscan2
- VPS50 | c.559T>G p.L187V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52494898; called by muse, mutect2, varscan2
- VSIR | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56464948; called by muse, mutect2, varscan2
- XIRP2 | c.9139C>T p.R3047C (on ENST00000628543; = p.R3222C on NM_152381.6) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765119236, COSV54694932; called by muse, mutect2, varscan2
- XPO4 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55007629; called by muse, mutect2, varscan2
- XPO5 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV54830293; called by muse, mutect2, varscan2
- ZC3H3 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.387); catalogued as rs189845798, COSV52790013; called by muse, mutect2, varscan2
- ZC4H2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV62003540; called by muse, mutect2, varscan2
- ZCWPW2 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV67499054; called by muse, mutect2, varscan2
- ZFC3H1 | c.4637C>G p.S1546C | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV66432830, COSV66432918; called by muse, mutect2, varscan2
- ZFHX3 | c.8447C>T p.P2816L | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.454); catalogued as COSV51719317; called by muse, mutect2, varscan2
- ZHX1 | c.1721A>G p.E574G | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52876624; called by muse, mutect2, varscan2
- ZNF205 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV54620993; called by muse, mutect2, varscan2
- ZNF229 | c.2356C>T p.H786Y | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52162042; called by muse, mutect2, varscan2
- ZNF251 | c.1713T>A p.Y571* | Nonsense Mutation (SNP) | VAF 34/75 reads (45%) | catalogued as COSV52957494; called by muse, mutect2, varscan2
- ZNF319 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV54622240; called by muse, mutect2, varscan2
- ZNF354B | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as rs558101520, COSV59366295; called by muse, mutect2, varscan2
- ZNF440 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58371189; called by muse, mutect2, varscan2
- ZNF493 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV62750131; called by muse, mutect2, varscan2
- ZNF609 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs142077559, COSV58583480; called by muse, mutect2, varscan2
- ZNF648 | c.1510T>A p.F504I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV60571050; called by muse, mutect2, varscan2
- ZNF665 | c.1717C>T p.R573C (on ENST00000600412; = p.R638C on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.33); catalogued as rs752223623, COSV67215219; called by muse, mutect2, varscan2
- ZNF682 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as rs1251503798, COSV62067189; called by muse, mutect2, varscan2
- ZNF714 | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV52512086; called by muse, mutect2, varscan2
- ZNF782 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV56652671; called by muse, mutect2, varscan2
- ZNF782 | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.108); catalogued as COSV56652418, COSV56652680; called by muse, mutect2, varscan2
- ZNF823 | c.1367C>T p.S456F (on ENST00000341191 / NM_001297610.2; = p.S412F on NM_017507.2) | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs750804371, COSV57873860; called by muse, mutect2, varscan2
- ZNF92 | c.1744G>A p.E582K (on ENST00000328747 / NM_152626.4; = p.E513K on NM_007139.4) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV60874190; called by muse, mutect2, varscan2
- ZNF99 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs200967349, COSV101233885, COSV68055809; called by muse, mutect2, varscan2
- ZSCAN20 | c.2666C>T p.A889V | Missense Mutation (SNP) | VAF 130/143 reads (91%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.754); catalogued as COSV63682824; called by muse, mutect2, varscan2
- ZSCAN25 | c.4C>T p.L2F | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs770539317, COSV53553128; called by muse, mutect2, varscan2
- EIF4A2 | c.581del p.K194Rfs*11 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- EPS15L1 | c.50_52delinsTG p.S17Lfs*27 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by pindel, varscan2*
- IGHV2-26 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- IGHV4-39 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- MORC1 | c.2727_2728del p.R910Kfs*4 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | called by mutect2, pindel, varscan2
- MRC1 | c.3373C>T p.L1125F | Missense Mutation (SNP) | VAF 244/582 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SPATA31A1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEF2 | c.3417del p.W1139Cfs*8 | Frame Shift Del (DEL) | VAF 49/84 reads (58%) | called by mutect2, pindel, varscan2
- TRAV13-2 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- TRDV1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- AADACL3 | c.528C>T p.S176= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV60199056, COSV60199164; called by muse, mutect2, varscan2
- AADACL4 | c.345C>T p.I115= | Silent (SNP) | VAF 28/33 reads (85%) | catalogued as rs769304847, COSV66106321; called by muse, mutect2, varscan2
- ABCC12 | c.1056C>T p.I352= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs771234580, COSV60911571; called by muse, mutect2, varscan2
- ABCC8 | c.969C>T p.I323= | Silent (SNP) | VAF 150/369 reads (41%) | catalogued as rs748659098, COSV56850831; called by muse, mutect2, varscan2
- ABCC9 | c.2799G>A p.E933= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs1565735141, COSV53972501, COSV99684647; ClinVar: likely benign; called by muse, varscan2
- AC004997.1 | c.858C>T p.I286= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs529764080, COSV53164325; called by muse, mutect2, varscan2
- AC132217.2 | c.69C>T p.T23= | Silent (SNP) | VAF 46/103 reads (45%) | catalogued as COSV56098939; called by muse, mutect2, varscan2
- ACSF3 | c.1341C>T p.F447= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV58078545; called by muse, mutect2, varscan2
- ACTL8 | c.570G>A p.K190= | Silent (SNP) | VAF 43/49 reads (88%) | catalogued as rs765073774, COSV64861475; called by muse, mutect2, varscan2
- ACVR1C | c.981G>A p.K327= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV54646367; called by muse, mutect2, varscan2
- ADAM11 | c.486G>A p.G162= | Silent (SNP) | VAF 28/62 reads (45%) | catalogued as COSV52345017; called by muse, mutect2, varscan2
- ADAM2 | c.1143C>T p.F381= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV55862386, COSV99696663; called by muse, mutect2, varscan2
- ADCY8 | c.1803C>T p.I601= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as rs771961643, COSV53900335; called by muse, mutect2, varscan2
- ADGRL1 | c.2100G>A p.E700= (on ENST00000340736 / NM_001008701.3; = p.E695= on NM_014921.5) | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV100529544; called by muse, mutect2, varscan2
- AGXT | c.309G>A p.G103= | Silent (SNP) | VAF 56/123 reads (46%) | catalogued as rs145419586; called by muse, mutect2, varscan2
- AHNAK2 | c.5583C>T p.S1861= | Silent (SNP) | VAF 89/254 reads (35%) | catalogued as rs1387529285, COSV100317591; called by muse, mutect2, varscan2
- AKAP1 | c.1779C>T p.F593= | Silent (SNP) | VAF 62/129 reads (48%) | catalogued as COSV58470446; called by muse, mutect2, varscan2
- ALDH3B2 | c.1152C>T p.L384= | Silent (SNP) | VAF 79/181 reads (44%) | catalogued as COSV62428328; called by muse, mutect2, varscan2
- ALOXE3 | c.1848C>T p.T616= | Silent (SNP) | VAF 42/81 reads (52%) | catalogued as COSV59075765; called by muse, mutect2, varscan2
- ALPK1 | c.3651C>T p.F1217= | Silent (SNP) | VAF 55/109 reads (50%) | catalogued as COSV51585274, COSV51592716; called by muse, mutect2, varscan2
- ANKS1B | c.2455T>C p.L819= (on ENST00000547776 / NM_152788.4; = p.L45= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV60358731; called by muse, varscan2
- ANO5 | c.708G>A p.G236= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV61085111; called by muse, mutect2, varscan2
- ANO5 | c.2628C>T p.L876= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV61083915; called by muse, mutect2, varscan2
- ANO9 | c.621G>A p.T207= | Silent (SNP) | VAF 14/20 reads (70%) | catalogued as rs746089671, COSV60449380; called by muse, mutect2, varscan2
- AOC3 | c.1011C>T p.F337= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV53826721; called by muse, mutect2, varscan2
- AOX1 | c.3213C>T p.H1071= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV53496037; called by muse, mutect2, varscan2
- APOB | c.10146G>A p.E3382= | Silent (SNP) | VAF 257/645 reads (40%) | catalogued as COSV51936120, COSV99265135; called by muse, mutect2, varscan2
- ATG13 | c.157T>C p.L53= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV56319533; called by muse, mutect2, varscan2
- ATP2A2 | c.114C>A p.S38= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV58044440; called by muse, mutect2, varscan2
- ATP8A2 | c.774G>A p.G258= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV54952948; called by muse, mutect2, varscan2
- ATP8B4 | c.1674T>C p.Y558= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV52715930; called by muse, mutect2, varscan2
- ATR | c.3798C>T p.A1266= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs760913107, COSV63386734; called by muse, mutect2, varscan2
- BAAT | c.960C>T p.F320= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV52288251; called by muse, mutect2, varscan2
- BACH2 | c.2310G>A p.L770= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs372285524; called by muse, mutect2, varscan2
- BANK1 | c.891G>A p.E297= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs1384334588, COSV59843058; called by muse, mutect2, varscan2
- BCL11B | c.1329C>T p.I443= (on ENST00000357195 / NM_001282237.2; = p.I372= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs554392409, COSV61735666; called by muse, mutect2, varscan2
- BMP15 | c.615C>T p.L205= | Silent (SNP) | VAF 43/45 reads (96%) | catalogued as COSV53140541; called by muse, mutect2, varscan2
- BPTF | c.5706C>T p.S1902= | Silent (SNP) | VAF 60/162 reads (37%) | catalogued as rs1354153166, COSV58837524; called by muse, mutect2, varscan2
- BRINP1 | c.1707G>A p.G569= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV56300395; called by muse, mutect2, varscan2
- BSN | c.4902C>T p.A1634= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1231809306, COSV56518284; called by muse, mutect2, varscan2
- BTBD3 | c.1128C>T p.H376= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV99655895; called by muse, mutect2, varscan2
- C10orf62 | c.213C>T p.S71= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs942609041, COSV65705258; called by muse, mutect2, varscan2
- C1R | c.405C>T p.S135= (on ENST00000536053 / NM_001354346.2; = p.S121= on NM_001733.7) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV56925141; called by muse, mutect2, varscan2
- C1orf131 | c.675G>A p.K225= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV100009777; called by muse, mutect2, varscan2
- C2orf78 | c.822A>G p.Q274= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV68517630; called by muse, mutect2, varscan2
- CAND1 | c.834C>T p.A278= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV73338594; called by muse, mutect2, varscan2
- CDC42BPA | c.4851C>T p.I1617= (on ENST00000334218 / NM_001366019.2; = p.I1604= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV62011334; called by muse, mutect2, varscan2
- CDH22 | c.1014C>T p.A338= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV64837647; called by muse, varscan2
- CFAP54 | c.6075C>T p.L2025= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV61572331; called by muse, mutect2, varscan2
- CHD5 | c.1110G>A p.L370= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV52415103; called by muse, mutect2, varscan2
- CHD9 | c.3378A>T p.G1126= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV54610674; called by muse, mutect2, varscan2
- CHRNA9 | c.867C>T p.I289= | Silent (SNP) | VAF 62/127 reads (49%) | catalogued as COSV59574571; called by muse, mutect2, varscan2
- CNBD2 | c.465C>T p.F155= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs776078829, COSV62586836; called by muse, mutect2, varscan2
- CNTN5 | c.741C>T p.I247= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV54312240, COSV99681963; called by muse, mutect2, varscan2
- COBL | c.2592C>T p.S864= | Silent (SNP) | VAF 43/122 reads (35%) | catalogued as COSV99472715; called by muse, mutect2, varscan2
- COL19A1 | c.3015C>T p.I1005= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV59573915; called by muse, mutect2, varscan2
- COL5A1 | c.3492G>T p.P1164= | Silent (SNP) | VAF 52/119 reads (44%) | catalogued as COSV65669200, COSV65673230; called by muse, mutect2, varscan2
- COL5A3 | c.2865G>A p.E955= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV53410862; called by muse, mutect2, varscan2
- CRAMP1 | c.3345C>T p.V1115= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV51962343; called by muse, mutect2
- CRTAC1 | c.1002C>T p.I334= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as COSV54001927; called by muse, mutect2, varscan2
- CSMD2 | c.7140C>T p.F2380= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as COSV53914317; called by muse, mutect2, varscan2
- CTAGE6 | c.1242G>A p.E414= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV69917295; called by muse, mutect2, varscan2
- CYP2C19 | c.618G>A p.R206= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as rs762006669, COSV64907818; called by muse, mutect2, varscan2
- CYP4F2 | c.1449G>C p.A483= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV55617774, COSV55618257; called by muse, mutect2, varscan2
- CYRIA | c.912C>T p.F304= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV62865127; called by muse, mutect2, varscan2
- DBX2 | c.822T>A p.S274= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as COSV60337802; called by muse, mutect2
- DCC | c.4077G>A p.P1359= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs571287631, COSV71432561; called by muse, varscan2
- DDX53 | c.138C>T p.S46= | Silent (SNP) | VAF 22/26 reads (85%) | catalogued as COSV60069083; called by muse, mutect2, varscan2
- DNAAF1 | c.711C>T p.I237= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1310959604, COSV100533680; called by muse, mutect2, varscan2
- DNAH17 | c.9840C>T p.S3280= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV101102386; called by muse, mutect2, varscan2
- DNAH17 | c.3027G>A p.G1009= | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as COSV101101894, COSV67754744; called by muse, mutect2, varscan2
- DNAJA3 | c.138C>T p.P46= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs777998359, COSV52162070; called by muse, mutect2, varscan2
- DPF1 | c.537C>T p.D179= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV100831491; called by muse, mutect2, varscan2
- DPH1 | c.732C>T p.P244= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV53984725, COSV53985029; called by muse, mutect2, varscan2
- DPP10 | c.1323G>A p.L441= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV59687962; called by muse, mutect2, varscan2
- DSG1 | c.798C>T p.I266= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV57132922; called by muse, mutect2, varscan2
- EEPD1 | c.213C>T p.I71= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV54198519; called by muse, mutect2, varscan2
- EHD3 | c.792C>T p.I264= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV59030845; called by muse, mutect2, varscan2
- EP300 | c.4860C>T p.P1620= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV54329875; called by muse, mutect2, varscan2
- ERC2 | c.1032G>A p.V344= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs1031350431, COSV55611741; called by muse, mutect2, varscan2
- EXOC3L2 | c.2034C>T p.P678= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV99374534; called by muse, mutect2, varscan2
- F11 | c.1164C>T p.I388= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as rs1165954112, COSV53001317; called by muse, mutect2, varscan2
- FAM135A | c.4053C>T p.T1351= (on ENST00000370479 / NM_001351599.1; = p.T1138= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV52051778; called by muse, mutect2, varscan2
- FAM9B | c.42C>T p.V14= | Silent (SNP) | VAF 54/58 reads (93%) | catalogued as COSV59119159; called by muse, mutect2, varscan2
- FAT2 | c.8199G>A p.E2733= | Silent (SNP) | VAF 49/58 reads (84%) | catalogued as COSV55820129; called by muse, mutect2, varscan2
- FAT3 | c.621C>T p.H207= | Silent (SNP) | VAF 218/492 reads (44%) | catalogued as rs746117341, COSV53113475; called by muse, mutect2, varscan2
- FAT3 | c.11721C>T p.I3907= | Silent (SNP) | VAF 186/446 reads (42%) | catalogued as COSV53113542, COSV99966210; called by muse, mutect2, varscan2
- FBXL13 | c.402C>T p.S134= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV57538392; called by muse, mutect2, varscan2
- FBXL4 | c.495T>C p.N165= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100014136; called by muse, mutect2, varscan2
- FBXO43 | c.1761G>A p.R587= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs747435922, COSV71054022; called by muse, mutect2, varscan2
- FBXW10 | c.1092G>A p.V364= | Silent (SNP) | VAF 67/185 reads (36%) | catalogued as rs1356459957, COSV57317368; called by muse, mutect2, varscan2
- FOXC2 | c.561C>T p.P187= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV57444785; called by muse, mutect2, varscan2
- FRAS1 | c.1035G>A p.R345= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV53612150; called by muse, mutect2, varscan2
- FSHR | c.471C>T p.I157= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100436637, COSV58624028; called by muse, mutect2, varscan2
- FUT9 | c.264C>T p.I88= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV100133427, COSV56142443; called by muse, mutect2, varscan2
- GALNT17 | c.990C>T p.F330= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs760735142, COSV61163212; called by muse, mutect2, varscan2
- GDAP1 | c.267G>A p.E89= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as COSV55185667; called by muse, mutect2, varscan2
- GPC6 | c.1476C>T p.S492= | Silent (SNP) | VAF 84/193 reads (44%) | catalogued as COSV65512572; called by muse, mutect2, varscan2
- GPR137C | c.966C>T p.F322= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV58705055; called by muse, mutect2, varscan2
- GPR158 | c.3291G>A p.E1097= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV66270688, COSV66276660; called by muse, mutect2, varscan2
- GPR158 | c.3534C>A p.T1178= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV66270696; called by muse, mutect2, varscan2
- GPR32 | c.210C>T p.F70= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV54514392, COSV54514638; called by muse, mutect2, varscan2
- GRIN2A | c.363C>T p.F121= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs145961628, COSV58026414; called by muse, mutect2, varscan2
- H2BC18 | c.177C>T p.A59= | Silent (SNP) | VAF 87/233 reads (37%) | catalogued as rs782055162, COSV58943679; called by muse, mutect2, varscan2
- HCRTR2 | c.127C>T p.L43= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV63795991, COSV63797908; called by muse, varscan2
- HYDIN | c.4548G>A p.R1516= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs750085486, COSV66870554; called by muse, mutect2, varscan2
- HYDIN | c.4425C>T p.I1475= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as rs752475652, COSV66832247; called by mutect2, varscan2
- IGFN1 | c.2715G>A p.T905= (on ENST00000295591 / NM_001367841.1; = p.T3362= on NM_001164586.2) | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs368398343, COSV55173046; called by muse, mutect2, varscan2
- IGHV3-73 | c.276C>T p.S92= | Silent (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
218 further variants in this file (0 protein-altering or splice-affecting, 195 silent, 23 other) are not listed here.
